Somatic mutation profile of tumor specimen TCGA-DD-A3A6-01A (aliquot TCGA-DD-A3A6-01A-11D-A22F-10) from TCGA case TCGA-DD-A3A6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 72.1 years (26,319 days).
Specimen TCGA-DD-A3A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d328303-3bd4-41fb-ab82-730ab1c107c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A6-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A6-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13404eed-ca4d-4111-a92f-97859229cc92

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs771927361, COSV53310921; called by muse, mutect2, varscan2
- C20orf96 | c.838C>T p.P280S (on ENST00000360321 / NM_153269.3; = p.P279S on NM_080571.1) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV64404088; called by mutect2, varscan2
- CER1 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66603688; called by mutect2, varscan2
- CPEB3 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs773585852, COSV56459947, COSV99798789; called by muse, mutect2, varscan2
- DPF2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs994854120, COSV52890510; called by muse, mutect2
- EPHA3 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV60716121, COSV60722262; called by muse, mutect2
- LBR | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs977194928, COSV55290414; called by muse, mutect2, varscan2
- LEXM | c.115T>C p.S39P | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV64023493; called by muse, mutect2
- MBD3L2 | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61589132; called by muse, mutect2
- MYO1H | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1369198344, COSV100183131, COSV60448338; called by muse, mutect2, varscan2
- NF2 | c.431dup p.Y144* | Nonsense Mutation (INS) | VAF 9/64 reads (14%) | catalogued as CI045510, CI983522, COSV58520618; called by mutect2, pindel, varscan2
- SERGEF | c.779A>C p.H260P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56384844, COSV56385398; called by muse, mutect2, varscan2
- SPRR1B | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV61067887; called by muse, mutect2
- TAF1L | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs967153095, COSV54256337, COSV54256950; called by muse, mutect2, varscan2
- TENM3 | c.4895A>G p.Y1632C | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69314027; called by muse, mutect2, varscan2
- TTN | c.51884G>A p.R17295Q (on ENST00000591111; = p.R9871Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | PolyPhen possibly damaging (0.889); catalogued as rs745914315, COSV60199761; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTL6B | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2
- FUT8 | c.1007_1008insA p.R337Pfs*44 (on ENST00000360689 / NM_001371534.1; = p.R174Pfs*44 on NM_004480.4) | Frame Shift Ins (INS) | VAF 9/96 reads (9%) | called by mutect2, pindel
- TSC2 | c.3511del p.A1171Lfs*20 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, varscan2
- CFHR1 | c.795G>A p.P265= | Silent (SNP) | VAF 41/472 reads (9%) | catalogued as rs766719031, COSV57628147; called by muse, mutect2
- IGHV7-81 | c.279C>T p.T93= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- PARP16 | c.246C>T p.A82= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV56035981; called by muse, mutect2
- STRIP2 | c.1923G>C p.P641= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV50806081; called by muse, mutect2, varscan2
